Gene-level copy-number profile of tumor specimen HTMCP-03-06-02098-01B from CGCI case HTMCP-03-06-02098, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 64.2 years (23,441 days).
Specimen HTMCP-03-06-02098-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f78f6b1e-1d61-40fb-95c0-0cea80ffddb8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02098-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,241 have no estimate.
https://portal.gdc.cancer.gov/files/5c6dd1d1-aec9-4664-a0db-43151b005593

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 2,246; copy number 2: 14,239; copy number 3: 32,538; copy number 4: 6,468; copy number 5: 2,547; copy number 6: 323; copy number 7: 2; copy number 8: 2; copy number 9: 2; copy number 10: 3; copy number 26: 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:57,204,379–57,204,799, 1 gene: MTCO2P3.
- chr14:106,421,711–106,422,218, 1 gene (within-gene range 0–1): IGHV4-39.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–1): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–1): IGHV3-43.
- chr16:74,393,076–74,421,953, 2 genes: AC009053.4, CLEC18B.
- chr22:15,572,089–15,573,265, 1 gene: AP000533.1.
- chr22:21,282,881–21,284,161, 1 gene (within-gene range 0–3): POM121L8P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 10 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:201,507,241–201,584,367, 2 genes, copy number 9 (within-gene range 5–9): AC096677.1, RPS10P7.
- chr1:209,428,817–209,432,838, 2 genes, copy number 8: MIR205HG, MIR205.
- chr1:216,194,051–216,204,366, 2 genes, copy number 7 (within-gene range 5–7): USH2A-AS1, MRPS18BP1.
- chr14:18,333,726–18,341,859, 1 gene, copy number 26: CR383658.1.
- chr14:18,967,434–19,003,752, 3 genes, copy number 10: POTEM, AL929601.3, RNU6-1239P.

Autosomal genes at a single copy (total copy number 1): 2,246. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
